Somatic mutation profile of tumor specimen MP2PRT-PAVHEV-TBP1-A (aliquot MP2PRT-PAVHEV-TBP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVHEV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,298 days).
Specimen MP2PRT-PAVHEV-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03dec97d-5591-445b-a3fd-67387f161e13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHEV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHEV-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b3560b4-972c-412e-9cab-72b17ab5a89d

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 38/311 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121918468, CM043335, CM096577, COSV100692090, COSV61005148; ClinVar: pathogenic; called by mutect2, varscan2
- ARFGEF3 | c.5407G>A p.A1803T | Missense Mutation (SNP) | VAF 140/559 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs373484827; called by muse, mutect2, varscan2
- CLCNKA | c.1468G>C p.E490Q | Missense Mutation (SNP) | VAF 150/606 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1421131685, COSV100509946; called by muse, mutect2, varscan2
- LOXHD1 | c.5740G>A p.G1914R (on ENST00000642948; = p.G1852R on NM_144612.7) | Missense Mutation (SNP) | VAF 81/344 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727504988; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR51I1 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 104/480 reads (22%) | catalogued as rs757821983, COSV66507509; called by muse, mutect2
- COMMD4 | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 75/350 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNTT | c.123_124insGTGTGGGGGGGCT p.K42Vfs*5 | Frame Shift Ins (INS) | VAF 96/418 reads (23%) | called by mutect2, pindel, varscan2
- LRIT1 | c.1213C>A p.L405M | Missense Mutation (SNP) | VAF 60/485 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- LTF | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 15/442 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); called by muse, mutect2
- HTR2C | c.630C>T p.N210= | Silent (SNP) | VAF 271/389 reads (70%) | catalogued as rs782644122, COSV52222042; called by muse, mutect2, varscan2
- RYR2 | c.4296C>A p.I1432= | Silent (SNP) | VAF 69/244 reads (28%) | catalogued as COSV63704108; called by muse, mutect2, varscan2
